Somatic mutation profile of tumor specimen TCGA-B0-5094-01A (aliquot TCGA-B0-5094-01A-01D-1421-08) from TCGA case TCGA-B0-5094, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 62.9 years (22,965 days).
Specimen TCGA-B0-5094-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 466edf87-d661-448c-a21c-309cc2fba04d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5094-11A (Solid Tissue Normal), aliquot TCGA-B0-5094-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13385ac0-62f0-485d-9d91-6fb35e13c8a7

The open-access MAF lists 82 somatic variants for this specimen: 68 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 12, Frame Shift Del 5, Splice Site 2, Nonsense Mutation 2, Intron 1, In Frame Del 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEST1 | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1554963305, COSV56446205; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 94/210 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs5030830, CM941373, CM961426, COSV56544274, COSV56546980, COSV56570311; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.2342A>T p.K781M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV54034445; called by muse, mutect2, varscan2
- ACOX3 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 124/354 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773972773, COSV62713166; called by muse, mutect2, varscan2
- ACSM6 | c.587G>A p.W196* | Nonsense Mutation (SNP) | VAF 44/180 reads (24%) | catalogued as rs1475656696, COSV58979617; called by muse, mutect2, varscan2
- AIFM1 | c.1556C>A p.S519Y | Missense Mutation (SNP) | VAF 81/287 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54856848; called by muse, mutect2, varscan2
- ALS2CL | c.1537G>T p.D513Y | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59672913; called by muse, mutect2, varscan2
- ANKLE2 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 64/286 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61709777; called by muse, mutect2, varscan2
- B3GNT8 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as COSV54198954; called by muse, mutect2, varscan2
- CBL | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV50651628; called by muse, mutect2, varscan2
- CDK14 | c.124-2A>T p.X42_splice (on ENST00000380050 / NM_001287135.2; = p.X24_splice on NM_012395.3) | Splice Site (SNP) | VAF 18/105 reads (17%) | catalogued as COSV56045971; called by muse, mutect2, varscan2
- CHRM2 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as rs201165506, COSV57780063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLDN18 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59304176; called by muse, mutect2
- CPSF3 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53011081; called by muse, mutect2, varscan2
- CRYGB | c.413C>G p.P138R | Missense Mutation (SNP) | VAF 92/269 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53680776; called by muse, mutect2, varscan2
- CTDSP2 | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66080194; called by muse, mutect2, varscan2
- DISP3 | c.3429G>T p.W1143C | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53834204; called by muse, mutect2, varscan2
- DMGDH | c.275C>A p.A92E | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54867018, COSV99669345; called by muse, mutect2, varscan2
- DOP1A | c.1825C>G p.Q609E | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.106); catalogued as COSV52714977; called by muse, mutect2, varscan2
- EVX2 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV57964549; called by muse, mutect2, varscan2
- GNAO1 | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as rs1271540719, COSV52617978; called by muse, mutect2, varscan2
- HIVEP3 | c.4756G>A p.G1586S | Missense Mutation (SNP) | VAF 100/296 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.232); catalogued as rs771618421, COSV56020503; called by muse, mutect2, varscan2
- INSR | c.2039T>C p.L680P | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV57169659; called by muse, mutect2, varscan2
- ITPKB | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.194); catalogued as rs1189038655, COSV55266662; called by muse, mutect2
- KDM5A | c.1609G>A p.V537I | Missense Mutation (SNP) | VAF 101/186 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV66995094; called by muse, varscan2
- KDM5C | c.2392G>T p.E798* | Nonsense Mutation (SNP) | VAF 28/35 reads (80%) | catalogued as COSV64767516; called by muse, mutect2, varscan2
- KLHDC7B | c.898C>A p.P300T (on ENST00000395676; = p.P941T on NM_138433.5) | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV67465040, COSV67465246; called by muse, mutect2, varscan2
- LAMC2 | c.995G>C p.S332T | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.975); catalogued as COSV51458330; called by muse, mutect2, varscan2
- LOXL3 | c.1194T>G p.H398Q | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51210940; called by muse, mutect2, varscan2
- MAFB | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as rs1327781040, COSV64826947; called by muse, mutect2, varscan2
- MCOLN3 | c.980A>G p.K327R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV62015319; called by muse, mutect2, varscan2
- MYL10 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 65/251 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV56206984, COSV56207630; called by muse, mutect2, varscan2
- NCLN | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1413707948, COSV55743344; called by muse, mutect2, varscan2
- NR1I3 | c.863T>A p.L288Q (on ENST00000367982 / NM_001077480.3; = p.L284Q on NM_005122.5) | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV63468950; called by muse, mutect2, varscan2
- OR52B4 | c.372C>G p.H124Q | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1366535699, COSV68769326; called by muse, mutect2, varscan2
- PASD1 | c.1752G>C p.Q584H | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100949017, COSV64856831; called by muse, mutect2
- PBRM1 | c.4472del p.P1491Rfs*48 (on ENST00000296302 / NM_001366071.2; = p.P1384Rfs*48 on NM_018313.5) | Frame Shift Del (DEL) | VAF 25/53 reads (47%) | catalogued as COSV56285284; called by mutect2, pindel, varscan2
- PKHD1L1 | c.9893T>G p.I3298R | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV65749239; called by muse, mutect2, varscan2
- PRX | c.3340G>T p.G1114W | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV52524270; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2780C>A p.S927Y | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV51486183; called by muse, mutect2, varscan2
- RALGAPA1 | c.4200G>C p.M1400I | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as COSV51891891; called by muse, mutect2, varscan2
- RALYL | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV72823935; called by muse, mutect2, varscan2
- RASA1 | c.2434C>T p.H812Y | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.72); catalogued as rs778245184, COSV57199510; called by muse, mutect2, varscan2
- RIMKLB | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV55239157; called by muse, mutect2, varscan2
- RMC1 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 132/385 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1212599068, COSV52573531; called by muse, mutect2, varscan2
- RMI2 | c.401T>C p.M134T | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV56964308; called by muse, mutect2, varscan2
- RNASEL | c.1616T>C p.F539S | Missense Mutation (SNP) | VAF 124/390 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762441300, COSV62377550; called by muse, mutect2, varscan2
- RUFY3 | c.663T>G p.N221K | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV56916377; called by muse, mutect2, varscan2
- SCNN1A | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs768103022, COSV57436788; called by muse, mutect2, varscan2
- SLC25A13 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 82/308 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV55711527; called by muse, mutect2, varscan2
- SLC34A3 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as rs761862841, COSV63186940; called by muse, varscan2
- SYNE2 | c.12473C>T p.S4158F | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59962292; called by muse, mutect2, varscan2
- TENM4 | c.6529G>C p.V2177L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV53654567; called by muse, varscan2
- THBS2 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs779173134, COSV64681186; called by muse, mutect2, varscan2
- TLR6 | c.677C>A p.T226N | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV67935597; called by muse, mutect2, varscan2
- TTN | c.64748C>T p.P21583L (on ENST00000591111; = p.P14159L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/290 reads (8%) | PolyPhen benign (0.003); catalogued as rs762758398, COSV59937221; called by muse, mutect2
- UBR4 | c.6212A>G p.Y2071C | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs762856082, COSV64395759; called by muse, mutect2, varscan2
- USH2A | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56410172; called by muse, mutect2
- VPS13B | c.4062A>T p.E1354D | Missense Mutation (SNP) | VAF 103/412 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV62152138; called by muse, mutect2, varscan2
- XKR4 | c.1874G>A p.C625Y | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs756130370, COSV59301026; called by muse, mutect2, varscan2
- ZBBX | c.2277-2A>T p.X759_splice | Splice Site (SNP) | VAF 42/143 reads (29%) | catalogued as COSV56796869; called by muse, mutect2, varscan2
- ZNFX1 | c.1414A>G p.R472G | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV65577823; called by muse, mutect2, varscan2
- ARMC4 | c.1351dup p.Y451Lfs*54 | Frame Shift Ins (INS) | VAF 54/221 reads (24%) | called by mutect2, pindel, varscan2
- FBH1 | c.1187_1192del p.E396_K397del (on ENST00000362091 / NM_178150.3; = p.E447_K448del on NM_032807.4) | In Frame Del (DEL) | VAF 30/140 reads (21%) | called by mutect2, pindel, varscan2
- PAPOLG | c.674_681del p.A225Vfs*43 | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | called by mutect2, pindel, varscan2
- PEA15 | c.188_195delinsG p.I63Rfs*23 | Frame Shift Del (DEL) | VAF 42/202 reads (21%) | called by pindel, varscan2*
- PRKCQ | c.126del p.Q43Rfs*32 | Frame Shift Del (DEL) | VAF 50/215 reads (23%) | called by mutect2, pindel, varscan2
- RFC1 | c.567_568del p.S190Tfs*5 | Frame Shift Del (DEL) | VAF 23/85 reads (27%) | called by mutect2, pindel, varscan2
- C1QTNF4 | c.768C>G p.A256= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV56784176; called by muse, mutect2, varscan2
- CCDC181 | c.411T>C p.L137= | Silent (SNP) | VAF 53/277 reads (19%) | catalogued as COSV63157534; called by muse, mutect2, varscan2
- COL24A1 | c.525C>G p.V175= | Silent (SNP) | VAF 5/109 reads (5%) | catalogued as COSV65310793; called by muse, mutect2
- GDF15 | c.654G>T p.A218= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV53251497; called by muse, mutect2, varscan2
- GSDME | c.549C>T p.I183= | Silent (SNP) | VAF 57/303 reads (19%) | catalogued as rs367647197; called by muse, mutect2, varscan2
- LIN7A | c.354T>A p.L118= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as COSV54025513; called by muse, mutect2, varscan2
- NR1H3 | c.882G>C p.A294= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV68008372, COSV68008708; called by muse, mutect2, varscan2
- ODF3 | c.729T>C p.S243= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV57294732; called by muse, mutect2, varscan2
- PASK | c.2886C>G p.T962= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV52153280, COSV52157525; called by muse, mutect2, varscan2
- SERTAD4 | c.255G>A p.E85= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV65399878; called by muse, mutect2, varscan2
- SYT7 | c.384C>T p.H128= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as rs775485372, COSV55658115; called by muse, mutect2, varscan2
- VPS18 | c.2292G>T p.V764= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV55031721; called by muse, mutect2, varscan2
- ATXN2L | c.*75A>T | 3'UTR (SNP) | VAF 22/73 reads (30%) | catalogued as COSV57376345; called by muse, mutect2, varscan2
- DST | c.4296+4583G>T | Intron (SNP) | VAF 47/192 reads (24%) | catalogued as rs1563241728, COSV55031298; called by muse, mutect2, varscan2
